Gene-level copy-number profile of tumor specimen TCGA-TM-A7C3-01A from TCGA case TCGA-TM-A7C3, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 43.9 years (16,021 days).
Specimen TCGA-TM-A7C3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.f1dadf05-cdff-4900-8613-3edbd194c0bd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TM-A7C3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a782eda9-ebf0-449b-932f-fa08b42963b1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 2,607; copy number 3: 3,320; copy number 4: 42,748; copy number 5: 4,646; copy number 6: 3,416; copy number 7: 2,811; copy number 9: 111; copy number 11: 17; copy number 44: 54; copy number 48: 22; copy number 55: 40; copy number 67: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TM-A7C3-01A-11D-A32A-01): tumor purity 0.88, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 263 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,475,806–205,211,702, 53 genes, copy number 44: PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1.
- chr1:205,233,821–205,236,867, 1 gene, copy number 44: TMCC2-AS1.
- chr7:5,898,725–6,799,365, 33 genes, copy number 9 (within-gene range 7–9): CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP, ZDHHC4, AC079742.1, C7orf26, ZNF853, ZNF316, AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P, RSPH10B2.
- chr7:54,419,444–55,572,988, 19 genes, copy number 67 (within-gene range 7–67): SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.
- chr7:129,953,234–130,026,989, 1 gene, copy number 9 (within-gene range 7–9): AC073320.1.
- chr7:130,018,287–131,702,653, 51 genes, copy number 9–11: ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2.
- chr12:57,546,026–58,244,865, 40 genes, copy number 55 (within-gene range 4–55): KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr14:60,734,742–61,803,634, 21 genes, copy number 48: MNAT1, MAD2L1P1, AL160236.2, SRMP2, TRMT5, AL160236.1, RNU6-398P, SLC38A6, PRKCH, TMEM30B, AL359220.1, AL355916.3, AL355916.2, LINC01303, AL355916.1, HIF1A-AS1, HIF1A, HIF1A-AS3, AL137129.1, SNAPC1, AL137918.1.
- chr14:61,831,861–61,832,369, 1 gene, copy number 48: COX4I1P1.
- chr19:44,631,573–45,351,520, 43 genes, copy number 9 (within-gene range 6–9): AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1, RELB, CLASRP, RNU6-611P, ZNF296, GEMIN7-AS1, GEMIN7, MARK4, PPP1R37, EIF5AP3, AC005757.1, NKPD1, TRAPPC6A, BLOC1S3, EXOC3L2, CKM, RPS16P9, KLC3.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
